Gene-level copy-number profile of tumor specimen C3L-08159-02 from CPTAC case C3L-08159, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 62.3 years (22,764 days).
Specimen C3L-08159-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 38fbadac-1707-4666-9b9f-d0dd69e56e16.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08159-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/e2337321-0b2b-40c6-abcb-4e6cee2cda56

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 20,075; copy number 2: 34,898; copy number 3: 3,391; copy number 4: 34; copy number 5: 355; copy number 6: 8; copy number 7: 62; copy number 8: 2; copy number 9: 28; copy number 11: 17; copy number 12: 1; copy number 13: 7; copy number 14: 10; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,354,570–186,680,901, 5 genes (within-gene range 0–2): AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV.
- chr20:14,547,184–14,758,056, 3 genes (within-gene range 0–1): RNF11P2, MACROD2-IT1, RPS10P2.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.
- chr21:28,048,404–28,228,667, 2 genes: LINC01697, LINC01695.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 493 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–594,768, 32 genes, copy number 5: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1.
- chr1:631,074–632,616, 2 genes, copy number 5 (within-gene range 1–5): MTCO1P12, AC114498.2.
- chr1:633,535–633,741, 1 gene, copy number 5 (within-gene range 1–5): MTATP8P1.
- chr8:105,546,089–106,060,524, 3 genes, copy number 5 (within-gene range 3–5): ZFPM2-AS1, AC103853.1, AC103853.2.
- chr8:105,826,570–128,220,803, 253 genes, copy number 5 (broad region; genes not listed).
- chr8:131,129,761–135,742,495, 63 genes, copy number 5 (broad region; genes not listed).
- chr19:28,316,705–28,396,428, 2 genes, copy number 8: AC005580.1, AC093074.1.
- chr19:29,205,320–30,228,715, 24 genes, copy number 9–13 (within-gene range 4–13): UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1.
- chr20:52,858,338–59,113,631, 113 genes, copy number 5–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
